TCGA case TCGA-HU-A4GN — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: National Cancer Center Korea. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f8a32cb0-8c3d-4bc2-8e53-561b89000be7

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: South Korea; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Tubular adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8211/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,288 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 912 days (2.5 years).
   Pathology details: Consistent pathology review: No; Lymph nodes positive: 1; Lymph nodes tested: 47.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mitomycin; Days to treatment start: 27 days; Days to treatment end: 100 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Polysaccharide-K; Days to treatment start: 107 days; Days to treatment end: 614 days (1.7 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxifluridine; Days to treatment start: 107 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thyroid gland; Age at diagnosis: 61.5 years (22,456 days); Days to diagnosis: 168 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 419 days (1.1 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 168 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Thyroid gland; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 640 days (1.8 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 912.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Barrett's Esophagus; Risk factors: Barrett's Esophagus.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HU-A4GN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 20 mg.
  Slide TCGA-HU-A4GN-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-HU-A4GN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HU-A4GN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-HU-A4GN-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 150 mg.
  Slide TCGA-HU-A4GN-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Tubular Type; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Daegu; History barretts esophageal indicator: Yes; History hpylori infection indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Copolang.
- Follow-up form: Lost to follow-up: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes; New tumor event site other: thyroid; Treatment outcome first course: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 912 days; disease-specific survival: no event (censored), 912 days; disease-free interval: event (new tumor event after initially disease-free), 168 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 168 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HU-A4GN-01A-11D-A253-01): tumor purity 0.36, ploidy 2, whole-genome doublings 0.
